TARGET case TARGET-15-SJMPAL043772 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d982a07f-f9c3-4e29-a1b0-d0b6fad4bddd

Demographics
Sex at birth: male; Age at index: 4 years; Vital status: Dead; Days to death: 771 days (2.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.9 years (1,796 days); Year of diagnosis: 2013; Days to last follow up: 771 days (2.1 years).

Follow-up (1 entry)
- Days to follow up: 771 days (2.1 years); First event: Relapse; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 0.5 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043772-04A, TARGET-15-SJMPAL043772-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043772-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 771
- Protocol: St. Jude
- WBC at Diagnosis: 0.5
- Karyotype: 47,XY,t(1;12)(q21;p13),del(5)(q32q35),del(9)(q13q32),+22
- WHO ALAL Classification: T/M
- WHO Dx: AML
- WHO RL1: AML
- WHO RL2: T/M
